CCG case CUPP-B5XR — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fbb800d7-e327-4f94-a714-64e7d0110c2f

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Japan; Year of birth: 1942; Vital status: Dead; Days to death: 500 days (1.4 years); Year of death: 2014; Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8070/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 70.2 years (25,638 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 8th; AJCC clinical T: T0; AJCC clinical N: N3b; AJCC clinical M: M0; AJCC clinical stage: Stage IVB; AJCC pathologic T: T0; AJCC pathologic N: N3b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVB; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 31; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R1; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative.
2. Progression of the lung (histology not recorded by GDC). Age at diagnosis: 70.6 years (25,772 days); Year of diagnosis: 2013; Days to diagnosis: 134 days.
   Treatment given: Treatment type: Other; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 40; ECOG performance status: 3.
- Day 134 (progression): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 134 days.
- Follow-up contact recording only the day: day 500.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 43 kg; Height: 163 cm; BMI: 16.2.
- Timepoint category: Prior to Diagnosis; Comorbidities: COPD / Hyperlipidemia / Hypertension.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 80; Tobacco smoking onset year: 1997; Tobacco smoking quit year: 2007.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Cancer; Relationship sex at birth: male.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B5XR-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B5XR-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 34; Percent tumor nuclei: 76; Percent normal cells: 0; Percent necrosis: 12; Percent stromal cells: 54; Percent lymphocyte infiltration: 17; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
